FM case AD151 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/9cd89b06-ac5d-4ef2-8c82-34002be91fe6

Female, 61.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the uterus. Sample type: Tumor.
